Somatic mutation profile of tumor specimen RC-B65C-TBP1-A (aliquot RC-B65C-TBP1-A-1-0-D-A93N-47) from RC case RC-B65C, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: T-cell large granular lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,853 days).
Specimen RC-B65C-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1006c3a2-0844-402c-83ca-c1f07630d6d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65C-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65C-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2198aae9-96b7-4ac2-a331-f1412cf91d97

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Frame Shift Ins 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.2041C>T p.R681* (on ENST00000372530 / NM_001198934.2; = p.R653* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | catalogued as rs773077517, COSV55092633; called by muse, mutect2, varscan2
- AJAP1 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs199677222, COSV65450811; called by muse, mutect2, varscan2
- COL7A1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs748854484, COSV60395226, COSV60404401; called by muse, mutect2, varscan2
- KLK8 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs745851461, COSV51590331, COSV99143988; called by muse, mutect2, varscan2
- MME | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201338166; called by muse, mutect2, varscan2
- SNX29 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757685756, COSV60064836; called by muse, varscan2
- SOGA1 | c.2059_2061del p.N687del | In Frame Del (DEL) | VAF 42/132 reads (32%) | catalogued as rs1568722774; called by mutect2, varscan2
- STAT3 | c.1973A>G p.K658R | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV52886492; called by muse, mutect2, varscan2
- ANKRD12 | c.708dup p.L237Tfs*9 | Frame Shift Ins (INS) | VAF 35/140 reads (25%) | called by mutect2, pindel, varscan2
- DSG2 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FOXA1 | c.52T>A p.Y18N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.226); called by mutect2, varscan2
- KMT2D | c.16083dup p.K5362* | Frame Shift Ins (INS) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- NAA16 | c.2081C>G p.S694C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- PRRT4 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- ZNF236 | c.4748A>G p.D1583G | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- F13B | c.1549A>C p.R517= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- INTS13 | c.255A>C p.A85= | Silent (SNP) | VAF 28/78 reads (36%) | called by muse, varscan2
- ITIH5 | c.723T>C p.P241= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- NCAPD2 | c.3345G>T p.V1115= | Silent (SNP) | VAF 44/115 reads (38%) | called by mutect2, varscan2
- SLCO3A1 | c.660G>A p.T220= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs12594058; called by muse, mutect2, varscan2
- TBC1D8 | c.1596C>T p.Y532= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs368051194; called by muse, mutect2, varscan2
